Somatic mutation profile of tumor specimen TCGA-2Z-A9J6-01A (aliquot TCGA-2Z-A9J6-01A-11D-A382-10) from TCGA case TCGA-2Z-A9J6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.0 years (22,265 days).
Specimen TCGA-2Z-A9J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19c0c482-e216-4433-b8b5-da64457c2ca1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J6-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J6-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46c9a342-c69e-4be8-96b0-7a567af3ac08

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Frame Shift Del 2, Intron 1, Splice Site 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQR | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99334279; called by muse, mutect2, varscan2
- BAIAP2 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100348472; called by muse, mutect2, varscan2
- BICDL1 | c.319_321del p.E107del | In Frame Del (DEL) | VAF 38/150 reads (25%) | catalogued as rs1219974938; called by mutect2, pindel, varscan2
- CA14 | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.055); catalogued as COSV99354448; called by muse, mutect2, varscan2
- CD200R1 | c.155A>C p.K52T (on ENST00000471858 / NM_170780.3; = p.K75T on NM_138806.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV99867510; called by muse, mutect2, varscan2
- CD80 | c.467A>T p.N156I | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV99958338; called by muse, mutect2
- CDC42BPG | c.4389G>A p.P1463= | Splice Region (SNP) | VAF 34/76 reads (45%) | catalogued as rs1296648181, COSV61348880; called by muse, mutect2, varscan2
- CREBBP | c.5774C>G p.A1925G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV99270850; called by muse, mutect2, varscan2
- CSF2RA | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 412/762 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs111646204, COSV100817837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELF2 | c.1129G>A p.A377T (on ENST00000379550 / NM_001331036.2; = p.A317T on NM_006874.4) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99643079; called by muse, mutect2, varscan2
- EMSY | c.2953G>A p.D985N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV100595833; called by muse, mutect2, varscan2
- ETHE1 | c.623A>T p.E208V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99415757; called by muse, mutect2, varscan2
- GRIN2A | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100410418, COSV58022132; called by muse, mutect2, varscan2
- GSTK1 | c.272T>A p.M91K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100621813; called by muse, mutect2, varscan2
- HDAC7 | c.2497G>A p.G833S (on ENST00000427332; = p.G872S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV99316563; called by muse, mutect2, varscan2
- HSPG2 | c.7300G>A p.G2434R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs372361312, COSV101020866; called by muse, mutect2, varscan2
- IGSF10 | c.6931T>A p.F2311I | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99183651; called by muse, mutect2, varscan2
- ITIH6 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 101/145 reads (70%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs751017752, COSV54488614, COSV99513570; called by muse, mutect2, varscan2
- KDM5B | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99350968; called by muse, mutect2, varscan2
- LAMA3 | c.3173G>T p.G1058V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100557144; called by muse, mutect2, varscan2
- LTK | c.1813A>G p.S605G | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV99541059; called by muse, mutect2, varscan2
- METTL15 | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100328505; called by muse, mutect2, varscan2
- NLK | c.1205A>T p.H402L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV101311234; called by muse, varscan2
- PHC3 | c.105G>T p.Q35H (on ENST00000494943 / NM_001308116.2; = p.Q47H on NM_024947.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs375674359; called by muse, mutect2, varscan2
- PIP | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs376369577; called by muse, mutect2, varscan2
- PROKR2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as COSV99450468; called by muse, mutect2, varscan2
- RPRD2 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100955197; called by muse, mutect2, varscan2
- SLC13A3 | c.461T>A p.I154N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286911; called by muse, mutect2, varscan2
- SLC35F1 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100837751; called by muse, mutect2, varscan2
- SLC5A10 | c.1384G>A p.V462I (on ENST00000395645 / NM_001042450.4; = p.V478I on NM_152351.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs769478843, COSV99408237; called by muse, mutect2, varscan2
- SLC6A19 | c.1553T>C p.I518T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs1238368821, COSV99722475; called by muse, mutect2, varscan2
- SMAD2 | c.457T>G p.F153V | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100053822; called by muse, mutect2
- SMG7 | c.1571A>T p.K524I | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100750439; called by muse, mutect2, varscan2
- SPAG9 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100005475; called by muse, mutect2, varscan2
- TM7SF2 | c.697T>A p.Y233N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99659713; called by muse, mutect2, varscan2
- TTC3 | c.948C>G p.D316E | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100695746; called by muse, mutect2, varscan2
- UBE3A | c.1067T>A p.F356Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV51669611, COSV99217529; called by muse, mutect2, varscan2
- USP20 | c.498-1G>T p.X166_splice | Splice Site (SNP) | VAF 40/120 reads (33%) | catalogued as COSV100204510; called by muse, mutect2
- VCPIP1 | c.2527G>T p.G843C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100125713; called by muse, mutect2, varscan2
- WDR17 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99707919; called by muse, mutect2, varscan2
- ZNF180 | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs141416252; called by muse, mutect2, varscan2
- ZNF219 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV100070488; called by muse, mutect2, varscan2
- MYH4 | c.4359dup p.D1454* | Frame Shift Ins (INS) | VAF 34/143 reads (24%) | called by mutect2, pindel, varscan2
- ST7 | c.493del p.M165* | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- TGOLN2 | c.904del p.T302Lfs*89 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | called by mutect2, pindel, varscan2
- C2orf78 | c.2439A>T p.S813= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV101281004; called by muse, mutect2, varscan2
- CACNA2D2 | c.501C>T p.D167= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as rs778207640, COSV99818008; called by muse, mutect2, varscan2
- CGREF1 | c.663C>A p.P221= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99565243; called by muse, mutect2, varscan2
- CHD7 | c.2136A>G p.K712= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV101418335; called by muse, mutect2
- CUBN | c.519A>G p.E173= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV100910618; called by muse, mutect2, varscan2
- FPGT | c.1650A>G p.S550= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs759467099, COSV100907343; called by muse, mutect2, varscan2
- HAPLN3 | c.981C>T p.H327= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV100613819; called by muse, mutect2
- HSPE1 | c.243A>G p.V81= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99291521; called by muse, mutect2, varscan2
- MYO18B | c.315G>C p.L105= | Silent (SNP) | VAF 10/183 reads (5%) | catalogued as COSV100124322; called by muse, mutect2
- OR7G1 | c.132C>T p.L44= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99528675; called by muse, mutect2, varscan2
- PKP4 | c.384A>G p.P128= | Silent (SNP) | VAF 78/236 reads (33%) | catalogued as rs938150867, COSV101081204; called by muse, mutect2, varscan2
- QTRT1 | c.1095G>A p.V365= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99139074; called by muse, mutect2, varscan2
- AMACR | c.739+1194A>G | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs371985040; called by muse, varscan2
